Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A69H, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A69H-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Liver, segments 4-8, resection

Number of tumors: one

Tumor histologic type: poorly differentiated carcinoma, favor hepatocellular carcinoma (see comment)

Histologic grade: poorly differentiated, grade 4 of 4 (Edmondson-Steiner classification)

Tumor size: 11 cm

Tumor location: right hepatic lobe

Tumor necrosis: focal (approximately 10% by gross examination)

Vascular invasion: present, extensive

Perineural invasion: not identified

Capsular invasion: not identified

Satellite lesions: not identified

Margins:

Parenchymal margin: negative but extremely close (0.13 mm) (possibly superseded by specimen B)

Vascular margins: negative

Bile duct margins: negative

Lymph nodes: none identified

Background liver: moderate macrovesicular steatosis (approximately 40%), focal ballooning degeneration of hepatocytes, and at least bridging fibrosis (see comment)

Additional findings: none

AJCC Pathologic TNM stage: pT2 pNX

NOTE: This pathologic stage assessment is based on information available at the time of this report and is subject to change pending clinical review and additional information.

ICD-O-3

NO:
Carcinoma, hepatocellular
8170/3
Site Liver C22.0
JW 6/13/13

[page 2 of 3]
B: Liver, segment 4B, excision

- No carcinoma identified
- Moderate macrovesicular steatosis

Comment:

Immunostains are performed on a section of tumor (block A5). The malignant cells are positive for cytokeratin AE1/AE3, CK8/18, and HepPar1. MOC-31 shows patchy moderate staining. CD10 is negative. The immunophenotype shows overlapping features between hepatocellular carcinoma and cholangiocarcinoma; however, given the strong HepPar1 staining, a poorly differentiated hepatocellular carcinoma is favored.

Special stains are performed on a section of background liver (block A9). A trichrome stain shows bridging fibrosis with areas suggestive of possible early nodule formation. There is a single focus of minor centrilobular perisinusoidal fibrosis. A reticulin stain shows no significant hepatic plate expansion. An iron stain shows mild to moderately increased iron staining within hepatocytes (grade 2 of 4) and increased iron staining within Kupffer cells. A PAS-D stain shows no PAS positive cytoplasmic inclusions.

Clinical History:

year-old male with a clinical diagnosis of hepatocellular carcinoma.

Gross Description:

Received are two appropriately labeled containers.

Container A:

Specimen Type: lobectomy, right

Specimen Weight: 850 grams

Measurement: 18 x 13 x 11 cm

Orientation: The specimen is oriented anatomically. The cut surface is inked blue. The specimen is received with a stitch in the center of the cut surface, which is inked red.

Capsule: focally thinned where the mass abuts over a region 4.5 x 4.5 cm near the dome; the capsule is brown and smooth

Mass: An 11.2 x 8.6 x 7.2 cm yellow/tan, poorly circumscribed mass is present. The mass has a central scar and focal hemorrhage. Less than 10% of the mass is necrotic. The mass

[page 3 of 3]
abuts but does not penetrate through the capsule. Less than 1 mm from the blue inked surgical margin.

Adjacent liver tissue: brown and grossly unremarkable without nodularity or fibrosis

Major portal vein/ hepatic vein: not involved

Gallbladder: not present

Block summary:

- A1 - vascular margins, cut surface
- A2 - vascular margins, capsule
- A3 - mass in closest approach to blue inked surgical margin
- A4 - mass in relation to capsule
- A5-A8 - representative sections of mass
- A9 - sections of grossly unremarkable liver taken away from mass

Container B is additionally labeled "liver, Segment 4B." It holds a 28.4 gram, 7.2 x 2.7 x 2.6 cm approximately wedge-shaped piece of liver. One surface is a tan smooth serosal surface, and the remaining two surfaces are cut parenchymal surfaces. One of the cut surfaces is designated by the surgeon with the stitch at the definitive margin. The definitive margin is inked blue, and the opposite surface is inked black. Serial sectioning reveals a tan firm parenchymal surface without masses, cysts or other lesions.

Block summary:

- B1-B2 - one full thickness section, bisected
- B3-B4 - one full thickness section, bisected
- B5-B6 - additional representative sections of blue inked representative margin

Source: NCI Genomic Data Commons file 0306042a-db92-4479-ab1c-8bbc3b0433fb (TCGA-BC-A69H.AE56DFF8-AF71-4217-A491-8F78543E186D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).